MMRF case MMRF_2548 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b9a0fbfd-dc87-4898-82a7-dfe771dbaed3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.4 years (20,959 days); ISS stage: I; Days to last known disease status: 645 days (1.8 years); Days to last follow up: 645 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 79 days; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 103 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 104 days; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 247 days; Days to treatment end: 249 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 251 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 250 days; Days to treatment end: 250 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 252 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 52.8 mg/dL; Immunoglobulin G 8.67 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.61 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.68 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 105 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.684 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.561 mg/dL; Immunoglobulin G 5.34 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 10.9 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 373 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.
- Day 183 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.669 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.129 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 271 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.589 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.824 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 11.5 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.83 mmol/L.
- Day 350 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 3.65 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 9.45 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 443 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 12.3 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 5.7 g/dL; Glucose 6 mmol/L.
- Day 517 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 5.03 µg/mL; Lactate Dehydrogenase 13.2 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 25 g/L; Total Protein 5.1 g/dL; Glucose 6.05 mmol/L.
- Day 645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.89 mg/dL; Immunoglobulin G 22.1 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 4.98 µg/mL; Lactate Dehydrogenase 11.3 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 7.21 mmol/L.

Other clinical attributes
- Day 1: Weight: 71 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2548_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2548_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
